Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAHP, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAHP-05A (Additional - New Primary).

Department of Pathology

Direct dial

Mobile

Internal postal address

E-mail

Date

Concerning

Summary pathology report

Left orchidectomy; seminoma; diameter < 1 cm; tumor confined to testis in available slides;
angio-invasion present; invasion in rete testis present.

Date of procurement (= date of orchidectomy):

pathologist

ICD-O-3
Seminoma NOS 9061/3
Site: @ Testis NOS C62.9
JW 3/13/14

professor of pathology

2nd Primary

Criteria	hw 1/18/14	Yes	No

Source: NCI Genomic Data Commons file a94b110e-9d70-4197-87b3-02a71fba66f0 (TCGA-2G-AAHP.6113FFF0-E13A-47A5-BB76-9D3C5EB3695D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).